Somatic mutation profile of tumor specimen 0D97Y0 from CCDI case PBBIDT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,814 days).
Specimen 0D97Y0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36cf3e81-a9f2-473a-a62c-42f0dbb00f11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D97Y1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23e73d50-2c52-4d2a-8778-6d1ca2a8b27e

The open-access MAF lists 18 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, Missense Mutation 5, Silent 4, Nonsense Mutation 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf37 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 324/749 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907136, CM120200, COSV99713098; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HHLA1 | c.1484A>G p.Y495C | Missense Mutation (SNP) | VAF 77/640 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs1023739222; called by muse, mutect2, varscan2
- MYO15B | c.8140C>T p.Q2714* | Nonsense Mutation (SNP) | VAF 162/434 reads (37%) | catalogued as rs1568230971; called by muse, mutect2, varscan2
- AATF | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 92/819 reads (11%) | called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 48/1492 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PCDHGB1 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 69/988 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYP | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP13 | c.4881C>T p.A1627= (on ENST00000394518 / NM_007200.5; = p.A1631= on NM_006738.6) | Silent (SNP) | VAF 311/711 reads (44%) | catalogued as rs376622204; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 12/348 reads (3%) | catalogued as rs1167537044; called by muse, mutect2
- NUP188 | c.3966G>A p.V1322= | Silent (SNP) | VAF 275/614 reads (45%) | catalogued as rs752413521; called by muse, mutect2, varscan2
- TMEM106B | c.363C>T p.I121= | Silent (SNP) | VAF 143/1440 reads (10%) | catalogued as rs766768609; called by muse, mutect2, varscan2
- GLUL | c.329-94G>A | Intron (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 15/308 reads (5%) | called by muse, mutect2
- MIER2 | c.493+91C>A | Intron (SNP) | VAF 3/37 reads (8%) | catalogued as rs1277114926; called by muse, mutect2
- NPHP4 | c.3232-70C>T | Intron (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- NTM | c.400+10C>T | Intron (SNP) | VAF 126/340 reads (37%) | catalogued as rs199839634; called by muse, mutect2, varscan2
- PSMC5 | c.97-12dup | Intron (INS) | VAF 78/437 reads (18%) | called by mutect2, varscan2
- UEVLD | c.-32G>T | 5'UTR (SNP) | VAF 41/272 reads (15%) | called by muse, mutect2, varscan2
